Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A18Y, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A18Y-01A (Primary Tumor).

1CD-0-3
Carcinoma, Papillary and Follicular 8340/3
Site Code: Thyroid C73.9

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Uni-nodular goiter.
PROCEDURE: Total thyroidectomy.
SPECIFIC CLINICAL QUESTION: Not answered.
OUTSIDE TISSUE DIAGNOSIS: Not answered.
PRIOR MALIGNANCY: Not answered.
CHEMOTHERAPY: Not answered.
ORGAN TRANSPLANT: Not answered.
IMMUNOSUPPRESSION: Not answered.
OTHER DISEASES: Not answered.

FINAL DIAGNOSIS:

PART 1: THYROID GLAND, TOTAL THYROIDECTOMY (19 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, ENCAPSULATED FOLLICULAR VARIANT, RIGHT LOBE, 1.4 CM (See comment).
- B. ONE ADDITIONAL FOCUS OF PAPILLARY MICROCARCINOMA, LEFT LOBE, LESS THAN 0.1 CM (See comment).
- C. NO ANGIOLYMPHATIC INVASION OR EXTRATHYROIDAL EXTENSION.
- D. ALL MARGINS ARE NEGATIVE.
- E. ONE (1) BENIGN LYMPH NODE.
- F. ONE NORMOCELLULAR PARATHYROID GLAND.
- G. AJCC STAGE : pT1bN0

PART 2: LYMPH NODE, LEVEL 6, DISSECTION - FOUR (4) BENIGN LYMPH NODES.

COMMENT:

A fine needle aspiration of the right lobe tumor identified a HRAS codon 61 mutation (molecular addendum to f and therefore molecular studies will not be repeated. Because the microcarcinoma is less than 0.1cm in size, no molecular studies will be performed.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Right Lobe, Left Lobe
TUMOR FOCALITY:	Multifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 1.4 cm
HISTOLOGIC TYPE**:	Papillary carcinoma, encapsulated follicular variant
PRIMARY TUMOR (pT):	pT1b
REGIONAL LYMPH NODES (pN):	pN0
EXTRANODAL EXTENSION:	Not identified
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Not identified
MARGINS:	Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION:	Not identified
ADDITIONAL PATHOLOGIC FINDINGS:	None Identified

Source: NCI Genomic Data Commons file 457efe81-7ecf-405e-a0b0-e1cd3ab8f695 (TCGA-BJ-A18Y.A36DAF35-DB45-47EA-B167-0B3A11D853C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).